Gene-level copy-number profile of tumor specimen TCGA-AO-A0JG-01A from TCGA case TCGA-AO-A0JG, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 49.3 years (18,021 days).
Specimen TCGA-AO-A0JG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.fda181a5-c1fa-4e2a-8df5-57b5cd18b0e0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A0JG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4aa1476f-b600-4609-95b9-13be9d0428e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,253; copy number 2: 42,054; copy number 3: 3,697; copy number 4: 183; copy number 5: 253; copy number 6: 253; copy number 8: 51; copy number 10: 11; copy number 13: 7; copy number 21: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A0JG-01A-31D-A087-01): tumor purity 0.54, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 630 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:82,806,515–82,808,021, 1 gene, copy number 5: CYP51A1P1.
- chr6:43,506,969–46,759,506, 69 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:59,712,916–60,608,418, 33 genes, copy number 5: OR10V1, STX3, OR10Y1P, OR10V3P, OR10V2P, AP000640.1, FABP5P7, MRPL16, CBLIF, TCN1, OOSP3, SRD5A3P1, OOSP1, AP000790.1, OOSP4A, OOSP4B, OOSP2, MS4A3, AP000790.2, MS4A2, LINC02705, MS4A6A, MS4A4A, MS4A4E, MIR6503, MS4A6E, MS4A7, MS4A14, MS4A5, MS4A1, MS4A12, MS4A13, MS4A19P.
- chr11:69,467,598–71,252,577, 40 genes, copy number 5 (within-gene range 1–5): AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:74,330,316–74,498,533, 11 genes, copy number 10: PGM2L1, HNRNPA1P40, AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2.
- chr11:76,860,867–81,040,236, 62 genes, copy number 13–21 (within-gene range 2–21) (broad region; genes not listed).
- chr17:48,762,235–53,106,358, 138 genes, copy number 6 (broad region; genes not listed).
- chr17:53,353,427–53,439,721, 3 genes, copy number 6: AC005341.1, AC090079.1, AC090079.2.
- chr17:56,836,387–63,427,699, 215 genes, copy number 5–8 (within-gene range 1–8) (broad region; genes not listed).
- chr17:64,308,316–64,954,177, 37 genes, copy number 5 (within-gene range 2–5): RPL31P57, PECAM1, Y_RNA, AC234063.1, MILR1, POLG2, ATP5MFP4, DDX5, MIR3064, MIR5047, CEP95, SMURF2, AC009994.1, MICOS10P2, ARHGAP27P1-BPTFP1-KPNA2P3, KPNA2P3, AC132812.1, BPTFP1, AC103810.3, PLEKHM1P1, MIR6080, MIR4315-2, RNU7-115P, AC103810.9, LRRC37A3, RN7SL404P, AC103810.6, AC103810.7, AC103810.2, AC103810.5, RDM1P4, AC103810.1, AC103810.4, AC037487.4, AC103810.8, AC037487.1, AC037487.3.
- chr17:80,169,992–80,966,371, 21 genes, copy number 5 (within-gene range 3–5): CARD14, AC087741.1, SGSH, SLC26A11, RNF213, AC124319.1, AC124319.2, AC124319.3, RNF213-AS1, ENDOV, MIR4730, AC120024.1, AC120024.4, NPTX1, AC120024.2, AC120024.3, RPL32P31, RPTOR, RPL31P7, AC016245.1, AC016245.2.

Autosomal genes at a single copy (total copy number 1): 10,832. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
